CCDI case PBBUNC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b3a89295-2dbd-4c57-a414-7e3861f58665

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,736 days).

Biospecimens (3 samples)
- Sample 0DHV61: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHV66: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHV6F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
